Somatic mutation profile of tumor specimen 0DV15C from CCDI case PBCMCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.7 years (7,180 days).
Specimen 0DV15C: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6fc26ad-6b00-4bc9-ae36-bf1f2cefd1f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25b1637a-04d4-48e0-bb8d-ea9538775d2f

The open-access MAF lists 67 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Intron 11, Nonsense Mutation 4, 5'UTR 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 183/467 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30BL | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 168/404 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1483509031, COSV99724670; called by muse, mutect2, varscan2
- ARHGAP20 | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 76/520 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs765414431, COSV52816406; called by muse, mutect2, varscan2
- ARID2 | c.5131C>T p.Q1711* | Nonsense Mutation (SNP) | VAF 226/873 reads (26%) | catalogued as COSV57615465; called by muse, mutect2, varscan2
- ATRX | c.6244G>T p.D2082Y | Missense Mutation (SNP) | VAF 198/239 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM062438, CM156091; called by muse, mutect2, varscan2
- COL4A5 | c.5041T>C p.C1681R | Missense Mutation (SNP) | VAF 107/140 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161157; called by muse, varscan2
- CUX1 | c.413C>T p.T138M (on ENST00000292535 / NM_181552.4; = p.T149M on NM_001913.5) | Missense Mutation (SNP) | VAF 89/581 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs964557562; called by muse, mutect2, varscan2
- FBN2 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs771516994, COSV52494356; called by muse, mutect2, varscan2
- MUC16 | c.5435G>A p.R1812K | Missense Mutation (SNP) | VAF 142/528 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.567); catalogued as rs1026014592; called by muse, mutect2
- NDUFV1 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 166/541 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV59596885; called by muse, mutect2, varscan2
- SATB1 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 225/480 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113152; called by muse, mutect2, varscan2
- SPDYE3 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.01); catalogued as rs979692829; called by muse, mutect2, varscan2
- ATP1A1 | c.2734A>G p.K912E | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- ATP6V1G3 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 157/590 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CASP4 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 238/620 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CDSN | c.1165G>T p.G389* | Nonsense Mutation (SNP) | VAF 70/723 reads (10%) | called by muse, mutect2
- CFAP92 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 209/543 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DNAH10 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- FGFR1 | c.905C>T p.P302L (on ENST00000447712 / NM_023110.3; = p.P300L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 246/793 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GON4L | c.3419C>A p.P1140H | Missense Mutation (SNP) | VAF 273/979 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HEATR5A | c.2063C>A p.T688N | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- HMCN2 | c.14195A>G p.N4732S | Missense Mutation (SNP) | VAF 96/729 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLF18 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 43/1534 reads (3%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.617); called by muse, mutect2
- MAGIX | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- MAGIX | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2
- MALRD1 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 22/477 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MUC17 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 210/1152 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NAV2 | c.7200G>A p.W2400* (on ENST00000396087 / NM_001244963.2; = p.W2341* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 168/644 reads (26%) | called by muse, mutect2, varscan2
- NDST4 | c.1057T>G p.Y353D | Missense Mutation (SNP) | VAF 71/529 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PCF11 | c.2503G>T p.E835* | Nonsense Mutation (SNP) | VAF 140/300 reads (47%) | called by muse, mutect2, varscan2
- QRFPR | c.1033T>C p.S345P | Missense Mutation (SNP) | VAF 185/462 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RBM17 | c.563-2A>G p.X188_splice | Splice Site (SNP) | VAF 11/328 reads (3%) | called by muse, mutect2
- STEAP3 | c.555G>C p.M185I | Missense Mutation (SNP) | VAF 291/683 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TENM3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 79/517 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THG1L | c.421T>G p.W141G | Missense Mutation (SNP) | VAF 30/1012 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TLK1 | c.1371A>T p.L457F | Missense Mutation (SNP) | VAF 202/519 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPAN12 | c.770C>G p.T257R | Missense Mutation (SNP) | VAF 82/1584 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2
- TTLL6 | c.1038C>A p.S346R (on ENST00000393382 / NM_001130918.3; = p.S39R on NM_173623.3) | Missense Mutation (SNP) | VAF 108/1305 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- ZNF12 | c.2007dup p.F670Ifs*15 (on ENST00000405858 / NM_016265.4; = p.F632Ifs*15 on NM_006956.3) | Frame Shift Ins (INS) | VAF 188/633 reads (30%) | called by mutect2, varscan2
- ABCC11 | c.2752C>A p.R918= | Silent (SNP) | VAF 262/641 reads (41%) | catalogued as rs139927866, COSV62325795; called by muse, mutect2, varscan2
- ANO4 | c.1806C>A p.V602= (on ENST00000392977 / NM_001286615.2; = p.V567= on NM_178826.4) | Silent (SNP) | VAF 139/565 reads (25%) | called by muse, mutect2, varscan2
- CHD7 | c.7905A>G p.K2635= | Silent (SNP) | VAF 316/834 reads (38%) | called by muse, mutect2, varscan2
- DRAM1 | c.285G>T p.V95= | Silent (SNP) | VAF 139/608 reads (23%) | called by muse, mutect2, varscan2
- EGLN3 | c.651A>G p.E217= | Silent (SNP) | VAF 94/262 reads (36%) | called by muse, mutect2, varscan2
- GPR37 | c.1110C>T p.Y370= | Silent (SNP) | VAF 246/1338 reads (18%) | catalogued as rs147406188, COSV58259202; called by muse, mutect2, varscan2
- LRFN3 | c.1524G>A p.T508= | Silent (SNP) | VAF 51/272 reads (19%) | catalogued as rs761353003; called by muse, mutect2, varscan2
- LRRC4C | c.744G>C p.L248= | Silent (SNP) | VAF 284/997 reads (28%) | called by muse, mutect2, varscan2
- NOTCH4 | c.4923T>C p.A1641= | Silent (SNP) | VAF 64/459 reads (14%) | called by muse, mutect2, varscan2
- NTSR2 | c.753C>A p.P251= | Silent (SNP) | VAF 87/445 reads (20%) | called by muse, mutect2, varscan2
- OR7A17 | c.288C>A p.G96= | Silent (SNP) | VAF 185/451 reads (41%) | called by muse, mutect2, varscan2
- SLC2A3 | c.393C>T p.C131= | Silent (SNP) | VAF 211/688 reads (31%) | catalogued as rs1318683023, COSV50002660; called by muse, mutect2, varscan2
- TMEM125 | c.405C>T p.A135= | Silent (SNP) | VAF 185/718 reads (26%) | catalogued as rs139782659; called by muse, mutect2, varscan2
- ACAP3 | c.105+24C>G | Intron (SNP) | VAF 171/494 reads (35%) | called by muse, mutect2, varscan2
- FLT4 | c.3332-47A>G | Intron (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- HSPA12A | c.836-45dup | Intron (INS) | VAF 232/546 reads (42%) | called by mutect2, pindel, varscan2
- MAPKAPK2 | c.893-96C>A | Intron (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- MIA2 | c.1955-86G>T | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- NPDC1 | c.113-39G>A | Intron (SNP) | VAF 83/308 reads (27%) | catalogued as rs764637718; called by muse, mutect2, varscan2
- PUM1 | c.1790-49A>T | Intron (SNP) | VAF 41/131 reads (31%) | called by muse, mutect2, varscan2
- SLC26A9 | c.553-71G>T | Intron (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- SMYD5 | c.206-46T>C | Intron (SNP) | VAF 153/348 reads (44%) | called by muse, mutect2, varscan2
- SNORD3B-2 | n.301T>A | RNA (SNP) | VAF 128/504 reads (25%) | catalogued as rs1483658132; called by muse, mutect2, varscan2
- STAB1 | c.4364-54C>T | Intron (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- SYTL3 | c.-77C>T | 5'UTR (SNP) | VAF 75/232 reads (32%) | catalogued as rs774477639, COSV51915290; called by muse, mutect2, varscan2
- USP53 | c.*49G>T | 3'UTR (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2, varscan2
- XKR8 | c.-15G>A | 5'UTR (SNP) | VAF 23/230 reads (10%) | called by muse, mutect2, varscan2
- ZP2 | c.2096-13G>T | Intron (SNP) | VAF 76/434 reads (18%) | called by muse, mutect2, varscan2
